Surgical pathology report (de-identified scan), TCGA case TCGA-AY-6197, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-6197-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

Colon, ascending, right hemicolectomy

Tumor Histologic Type: adenocarcinoma, colon primary (see comment)

Histologic Grade: low grade (grade 2 of 4, moderately differentiated)

Tumor Size: 8.2 cm

Tumor Location: cecum

Depth of Invasion: through muscularis propria and into pericolonic adipose tissue, no definitive penetration or perforation of visceral peritoneum identified

Lymphovascular Invasion: not identified

Perineural Invasion: not identified

Margins: negative

Proximal margin: 10.1 cm

Distal margin: 11.6 cm

Mesenteric vascular margin: 6.1 cm

Regional Lymph Nodes:

Total number with metastases: 0

Total number examined: 16

Additional Pathologic Findings: Focal mucinous differentiation (less than 10% of tumor), no significant intra- or peritumoral lymphoid response, fibrous obliteration of appendiceal lumen

AJCC PATHOLOGIC TNM STAGE: pT3 pN0

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Immunohistochemistry for mismatch repair protein expression:

MLH1: loss of nuclear expression (abnormal phenotype), positive internal control present

MSH2: normal phenotype

MSH6: normal phenotype

Comment:

Materials are submitted to the Molecular Pathology lab for microsatellite instability (MSI) testing. The results will be reported separately.

Clinical History:

colon cancer.

Gross Description:

Received is one appropriately labeled container, additionally labeled "ascending colon."

Specimen fixation: formalin

Parts of bowel received: terminal ileum (10.3 cm long x 4.1 cm in circumference), large bowel (18.7 cm long x 7.2 cm in

[page 2 of 3]
circumference), appendix (4.7 cm long x 1.0 cm in diameter) and pericolonic adipose tissue (21.2 x 6.5 x 6.5 cm)

Specimen length: please see "Parts of bowel received"

Orientation: proximal mucosal margin=blue, radial margin=red, distal mucosal margin=black

Tumor location: proximal ascending colon

Gross appearance of tumor: The mass is firm, pink/tan and fungating with raised borders and central ulceration. The mass involves the ileocecal valve.

Tumor dimensions: 8.2 x 5.1 x 2.5 cm (protruding into the lumen)

Circumferential growth: approximately 90% of lumen involved by mass

Gross depth of invasion: The mass extends through the muscularis propria and into the underlying adipose tissue.

Gross evidence of perforation through visceral peritoneum: no

Luminal obstruction: The lumen is obstructed and the diameter of the lumen at the tumor site is 1.4 cm.

Bowel circumference at tumor site: 8.7 cm

Gross distance of tumor from margins: The mass is 10.1 cm to the proximal margin, 11.6 cm to the distal margin, 3.4 cm to the lateral edge of the specimen margin, and 6.1 cm to the mesenteric pedicle margin.

Other comments: The terminal ileal mucosa is tan/gray and slightly granular. The uninvolved colonic mucosa is unremarkable. The appendix is unremarkable.

Lymph nodes: Sixteen lymph node candidates are identified ranging from 0.5 cm in greatest dimension up to 1.0 cm in greatest dimension.

Other remarkable findings: none

Tissue submitted for special investigation: Yes; normal and tumor given to [REDACTED]

Digital photograph taken: no

Block summary: (Inking: Proximal mucosal margin=blue, distal mucosal margin=black, radial margin=red)

A1 - proximal mucosal margin, en face

A2 - distal mucosal margin, en face

A3 - radial margin, en face

A4 - pedicle margin, en face

A5,A6 - full thickness section of mass, bisected

A7 - full thickness section of mass

A8 - additional section of mass into the underlying adipose tissue

A9 - mass with ileocecal valve

A10 - appendix

A11 - four lymph nodes

A12 - two lymph nodes, each bisected; one inked black

A13 - two lymph nodes, each bisected; one inked black

A14 - three lymph nodes, each bisected; one inked blue, one inked black

A15 - two lymph nodes

A16 - one lymph node, serially sectioned

A17 - one lymph node, serially sectioned

A18 - one lymph node, bisected

[page 3 of 3]
Light Microscopy:

Light microscopic examination is performed by [REDACTED]

For cases in which immunostains are performed, the following applies: Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the [REDACTED]
[REDACTED] These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

Signature

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 2b3bf325-c2be-44c3-8e17-77597731fe81 (TCGA-AY-6197.0255EFB9-D9FD-492F-861B-AB2472A790A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).